TCGA case TCGA-IF-A4AJ — Sarcoma (TCGA-SARC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Myomatous Neoplasms; Primary site: Bones, joints and articular cartilage of limbs; Tissue source site: University of Texas MD Anderson Cancer Center. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/4e8c570c-3cbe-4878-8b2c-b966868dd60d

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 80 years; Vital status: Dead; Days to death: 767 days (2.1 years).

Diagnoses (3)
1. Leiomyosarcoma, NOS (the primary disease): ICD-O-3 morphology code: 8890/3; ICD-10 code: C40.2; Tissue or organ of origin: Long bones of lower limb and associated joints; Site of resection or biopsy: Long bones of lower limb and associated joints; Classification of tumor: primary; Age at diagnosis: 80.7 years (29,469 days); Year of diagnosis: 1995; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Sites of involvement: Lung, NOS; Tumor focality: Unifocal.
   Pathology details: Measurement type: Pathologic; Tumor burden: 10.
   Pathology details: Consistent pathology review: Yes; Margin status: Uninvolved; Necrosis percent: 15; Necrosis present: Yes; Tumor depth descriptor: Deep.
   Pathology details: Measurement type: Radiologic; Tumor burden: 7.
   Pathology details: Measurement type: Radiologic; Measurement unit: Centimeters; Tumor length measurement: 7; Tumor width measurement: 5.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor length measurement: 10.
2. Metastasis of diagnosis 1 (Leiomyosarcoma, NOS), site: Lung, NOS. Age at diagnosis: 82.2 years (30,029 days); Days to diagnosis: 560 days (1.5 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
3. Metastasis of diagnosis 1 (Leiomyosarcoma, NOS), site: Brain, NOS. Age at diagnosis: 82.7 years (30,211 days); Days to diagnosis: 742 days (2.0 years); Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease.

Follow-up (3 entries)
- Day 560 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 560 days (1.5 years).
- Day 742 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Brain, NOS; Days to progression: 742 days (2.0 years).
- Days to follow up: 767 days (2.1 years); Disease response: With Tumor.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-IF-A4AJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 40 mg.
  Slide TCGA-IF-A4AJ-01A-01-TS1: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 100; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 15; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-IF-A4AJ-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-IF-A4AJ-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Initial weight: 130 mg.
  Slide TCGA-IF-A4AJ-11A-01-TSA: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 100; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 0.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor.
- Primary pathology: Histologic diagnosis: Leiomyosarcoma (LMS); Histologic subtype: Conventional leiomyosarcoma; Leiomyo major vessel involvement: No Major Vessel Involvement; Margin status: Negative; Tumor total necrosis: Moderate Necrosis (>=10, <50%); Disease multifocal indicator: No; Locoregional recurrence indicator: No; Metastatic disease confirmed: Yes; Metastasis site: Lung; Contiguous organ invaded: No.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Lower Extremity - Lower leg/calf.
- Primary pathology, Tumor sizes, Tumor size: Lesion radiologic length: 7; Lesion radiologic width: 5.
- Drug treatment: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 567; Days from index date to pharmaceutical treatment ended: 600; Pharmaceutical therapy drug name: Adriamycin; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Clinical Progressive Disease.
- Drug treatment, Therapy types: Pharmaceutical therapy type: Chemotherapy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 767 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 767 days; disease-free interval: event (new tumor event after initially disease-free), 560 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 560 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-IF-A4AJ-01A-11D-A24M-01): tumor purity 0.7, ploidy 2.86, whole-genome doublings 1.
